FM case AD9422 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Anus and anal canal.
https://portal.gdc.cancer.gov/cases/f7311e97-2e88-4416-b580-b75e99272e75

Female, 46.0 years: Basaloid carcinoma (ICD-O-3 8123/3) of the anus; metastasis biopsied or resected from the trachea. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
